Gene-level copy-number profile of tumor specimen ALCH-B385-TTP1-A from ALCHEMIST case ALCH-B385, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.9 years (24,453 days).
Specimen ALCH-B385-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d6be1c4-4cd2-4277-8d87-a947360863d6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B385-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/b0b29a09-e165-4703-99e3-fb7f12f611eb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 63; copy number 2: 18,146; copy number 3: 27,704; copy number 4: 9,762; copy number 5: 280; copy number 6: 1,060; copy number 7: 1,221; copy number 8: 149; copy number 10: 2; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,086,459–5,090,899, 1 gene: LINC02782.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:127,934,503–127,980,989, 3 genes: AL157935.1, DPM2, FAM102A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,376 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–149,556,361, 4 genes, copy number 12: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr4:3,889,356–3,902,594, 2 genes, copy number 7: OR7E163P, OR7E162P.
- chr5:58,198–1,634,005, 60 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr5:14,143,342–14,532,128, 2 genes, copy number 7: TRIO, AC016549.1.
- chr5:31,532,287–32,604,079, 31 genes, copy number 7: C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1.
- chr5:42,892,319–43,707,405, 33 genes, copy number 7 (within-gene range 6–7): PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT.
- chr5:53,883,942–57,320,020, 80 genes, copy number 7 (broad region; genes not listed).
- chr5:70,219,918–71,133,287, 17 genes, copy number 7: GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, CDH12P1, SERF1A, SMN1, AC139834.1, NAIP, GTF2H2, OCLNP1, NAIPP4, CDH12P4.
- chr8:69,987,415–145,066,685, 1,146 genes, copy number 7–10 (broad region; genes not listed).
- chr22:18,733,914–18,757,906, 1 gene, copy number 8: FAM230E.

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
